Surgical pathology report (de-identified scan), TCGA case TCGA-VQ-A91Z, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Barretos Cancer Hospital, specimen TCGA-VQ-A91Z-01A (Primary Tumor).

Collect date:

ICD O-3
Adenocarcinoma, tubular
8211/3
Site: Gastric antrum
C16.3
JW 3/18/14

PATHOLOGY REPORT:

PRIMARY SITE: Stomach (Antrum)

“Stomach:

Adenocarcinoma with the following features:

Site: antrum

Histologic pattern:

Tubular

Histologic grade II, moderately differentiated

Lauren classification: intestinal type

Largest tumor size: 5.0 cm

Ulceration: present

Local invasion:

To adjacent fat tissue

Tumor invasion type

Infiltrative

Inflammatory response

Moderate

Tumor implant in perivisceral fat

Not observed

Proximal margin

Uninvolved by neoplasia

Distal margin

Uninvolved by neoplasia

Neural invasion

Uninvolved by neoplasia

Lymphatic invasion

Present

Blood vessel invasion

Not observed

Greater omentum

Uninvolved by neoplasia

Lymph nodes:

Involved by neoplasia: 2 of 19 lymph nodes (2/19).

Distribution of lymph nodes:

- Greater curvature: 2 of 8 lymph nodes involved by neoplasia (2/8).

- Lesser curvature: uninvolved by neoplasia (0/11).

Diagnostic Discrepancy		☒
HPV Discrepancy		☒
Qual/Sync/Primary/Neopl		☒
Case is (uretic)	☒	☐

Source: NCI Genomic Data Commons file fff3b7c6-d311-4e14-a517-bf6970c07cff (TCGA-VQ-A91Z.07DCD268-1A4A-4B54-82C5-031A6E5E882D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).